Somatic mutation profile of tumor specimen TCGA-AO-A03O-01A (aliquot TCGA-AO-A03O-01A-11W-A019-09) from TCGA case TCGA-AO-A03O, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.4 years (25,362 days).
Specimen TCGA-AO-A03O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b84ccee-4b8e-4710-97d9-28e269a4e60b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A03O-10A (Blood Derived Normal), aliquot TCGA-AO-A03O-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca7975a5-b966-488e-a5d5-f2488766ebe8

The open-access MAF lists 82 somatic variants for this specimen: 65 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 13, Nonsense Mutation 6, In Frame Del 2, Frame Shift Del 2, Splice Site 1, 3'UTR 1, 5'Flank 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 70/99 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM29 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.268); catalogued as COSV63660717; called by muse, mutect2, varscan2
- ADAMTS20 | c.3350G>A p.C1117Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67127036; called by muse, mutect2, varscan2
- ADGRG2 | c.2464G>C p.G822R (on ENST00000379869 / NM_001079858.3; = p.G819R on NM_005756.4) | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.174); catalogued as COSV61337698; called by muse, mutect2, varscan2
- ARMCX2 | c.1587G>C p.L529F | Missense Mutation (SNP) | VAF 94/506 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57529358; called by muse, mutect2, varscan2
- ASCC3 | c.4696C>T p.R1566C | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757716813, COSV64972526; called by muse, mutect2, varscan2
- ASH1L | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV64205809, COSV64209548; called by muse, mutect2, varscan2
- ATP7A | c.3316G>C p.G1106R | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58443151, COSV58455426; called by muse, mutect2, varscan2
- ATRX | c.4152T>A p.F1384L | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as COSV64872120; called by muse, mutect2, varscan2
- CD99 | c.315A>T p.K105N | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV66989198; called by muse, mutect2, varscan2
- CNTN6 | c.1155A>T p.Q385H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63163053; called by muse, mutect2, varscan2
- CSMD3 | c.766A>T p.S256C | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99846444; called by muse, mutect2
- EIF3E | c.1265T>C p.I422T | Missense Mutation (SNP) | VAF 46/582 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV99623492; called by muse, mutect2
- ENGASE | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs941848248, COSV56134380; called by muse, mutect2, varscan2
- ERCC6 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs56397747, COSV63388105; called by muse, mutect2, varscan2
- FAM47C | c.1124T>A p.V375E | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV63723943; called by muse, mutect2, varscan2
- FIGN | c.2256C>G p.N752K | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV60763428, COSV60772167; called by muse, mutect2, varscan2
- FPR3 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 72/484 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); catalogued as rs918562779, COSV59328367; called by muse, mutect2, varscan2
- GPR26 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV52932808; called by muse, mutect2, varscan2
- IARS1 | c.3529C>T p.Q1177* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV65114107; called by muse, mutect2, varscan2
- INPP4B | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs377427325; called by muse, mutect2, varscan2
- KANK1 | c.2482G>C p.E828Q | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV100620078; called by muse, mutect2
- KIAA0895 | c.814C>G p.L272V (on ENST00000297063 / NM_001100425.2; = p.L221V on NM_015314.3) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV51708976; called by muse, mutect2, varscan2
- KRT1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1389424250, COSV52865137; called by muse, mutect2, varscan2
- LAS1L | c.1814G>C p.R605T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV56706492, COSV56708204; called by muse, mutect2, varscan2
- LCMT2 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1444150997, COSV59789569; called by muse, mutect2, varscan2
- MARF1 | c.1454A>T p.H485L | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.908); catalogued as COSV60020240; called by muse, mutect2, varscan2
- MCM3AP | c.4760G>A p.R1587H | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1437791500, COSV52436589; called by muse, mutect2, varscan2
- METTL24 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs748963544, COSV58823459; called by muse, mutect2
- MFSD9 | c.1305G>C p.E435D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV51492787; called by muse, mutect2, varscan2
- MICAL3 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.97); catalogued as COSV52892767; called by muse, mutect2, varscan2
- NARF | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1289357455; called by muse, mutect2
- OR5AK2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.139); catalogued as COSV58803873; called by muse, mutect2, varscan2
- OSMR | c.805A>C p.K269Q | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV57081417; called by muse, mutect2, varscan2
- PBX1 | c.772A>T p.N258Y | Missense Mutation (SNP) | VAF 57/446 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV63341320; called by muse, mutect2, varscan2
- PON2 | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56000493; called by muse, mutect2, varscan2
- RBBP9 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV61499763; called by muse, mutect2, varscan2
- RBFOX1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772938189, COSV60947261; called by muse, mutect2, varscan2
- RC3H1 | c.1426A>G p.I476V | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs974824786, COSV99281724; called by muse, mutect2
- SEMA5A | c.2464C>A p.P822T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV66785444; called by muse, mutect2, varscan2
- SFI1 | c.963_966del p.Y322Sfs*70 (on ENST00000400288 / NM_001007467.3; = p.Y322Sfs*97 on NM_014775.4) | Frame Shift Del (DEL) | VAF 33/112 reads (29%) | catalogued as COSV66289836; called by mutect2, pindel, varscan2
- SIN3A | c.1898T>C p.L633P | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64581922; called by muse, mutect2, varscan2
- SLCO1B3 | c.1363C>G p.P455A | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.105); catalogued as rs1565600521, COSV53933124; called by muse, mutect2, varscan2
- SORCS3 | c.2813G>A p.W938* | Nonsense Mutation (SNP) | VAF 87/916 reads (9%) | catalogued as COSV100863793, COSV63793449; called by muse, mutect2
- SPECC1 | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.279); catalogued as rs771455889, COSV54953296; called by muse, mutect2, varscan2
- SVIL | c.4166A>G p.E1389G (on ENST00000355867 / NM_021738.3; = p.E963G on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100881519; called by muse, mutect2
- SYBU | c.871C>T p.R291* (on ENST00000276646 / NM_001099754.2; = p.R290* on NM_017786.6) | Nonsense Mutation (SNP) | VAF 64/719 reads (9%) | catalogued as rs755632666, COSV99406607; called by muse, mutect2
- SYMPK | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs145063068; called by muse, mutect2, varscan2
- TFCP2 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 58/292 reads (20%) | catalogued as rs772267193, COSV56931480; called by muse, mutect2, varscan2
- TMC5 | c.2230T>A p.S744T (on ENST00000396229 / NM_001105248.1; = p.S498T on NM_024780.5) | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.288); catalogued as COSV54901220; called by muse, mutect2, varscan2
- TP53BP1 | c.4850T>G p.I1617S | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55496783; called by muse, mutect2, varscan2
- TRA2B | c.334-1G>C p.X112_splice | Splice Site (SNP) | VAF 17/120 reads (14%) | catalogued as COSV52024728, COSV52024848; called by muse, mutect2, varscan2
- TRIB1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs138022510; called by muse, mutect2
- UBE2D2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV54077205; called by muse, mutect2, varscan2
- USP15 | c.874A>G p.S292G (on ENST00000280377 / NM_001351159.2; = p.S263G on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as COSV54788267; called by muse, mutect2, varscan2
- VGLL3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs1032057055, COSV101051878, COSV67352465; called by muse, mutect2, varscan2
- VPS13B | c.1928T>C p.V643A | Missense Mutation (SNP) | VAF 194/1009 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV62016428; called by muse, mutect2, varscan2
- ZNF366 | c.1519T>A p.C507S | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59213963; called by muse, mutect2, varscan2
- ZNF532 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs373691715; called by muse, mutect2, varscan2
- ACACA | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 59/274 reads (22%) | called by muse, mutect2, varscan2
- MYH14 | c.3508G>A p.G1170S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- NCK1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 13/377 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.302); called by muse, mutect2
- PIK3CA | c.333_341del p.K111_L113del | In Frame Del (DEL) | VAF 69/191 reads (36%) | called by mutect2, pindel, varscan2
- RUNX1 | c.570_586del p.S191Afs*4 (on ENST00000344691 / NM_001001890.3; = p.S218Afs*4 on NM_001754.5) | Frame Shift Del (DEL) | VAF 28/42 reads (67%) | called by mutect2, pindel, varscan2
- TRIM5 | c.939_944del p.S314_E315del | In Frame Del (DEL) | VAF 72/357 reads (20%) | called by pindel, varscan2
- CDC42SE2 | c.249G>A p.A83= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs376595413; called by muse, mutect2, varscan2
- DGAT2L6 | c.660C>G p.V220= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV60717178; called by muse, mutect2, varscan2
- GABRG1 | c.678A>G p.E226= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV54950444; called by muse, mutect2, varscan2
- HCN1 | c.633A>G p.K211= | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as COSV100302107; called by muse, mutect2
- HTR1B | c.888C>T p.D296= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV64051132; called by muse, mutect2, varscan2
- LVRN | c.111C>T p.Y37= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV63496381; called by muse, mutect2
- PCDHGA3 | c.579G>A p.E193= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as COSV53905084, COSV53930227; called by muse, mutect2, varscan2
- PLXNC1 | c.1143C>T p.G381= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as COSV51569957; called by muse, mutect2, varscan2
- RGL3 | c.1380C>G p.A460= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV66506653; called by muse, mutect2
- SFRP2 | c.447C>T p.N149= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs375396684, COSV56837699; called by muse, mutect2
- TMEM43 | c.84G>A p.R28= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV55499581; called by muse, mutect2
- UBQLN2 | c.1704T>G p.A568= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100592833; called by muse, mutect2
- USP11 | c.1980C>T p.D660= (on ENST00000218348; = p.D617= on NM_001371072.1) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs144034150, COSV99511146; called by mutect2, varscan2
- AP000769.5 | chr11:65499150 C>G | 5'Flank (SNP) | VAF 11/36 reads (31%) | catalogued as rs11547521; called by muse, mutect2, varscan2
- KLRA1P | n.598C>G | RNA (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- NDE1 | c.1030+2942G>C | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs766128896; called by muse, mutect2
- UVSSA | c.*9037G>C | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs146249377, COSV61347110, COSV61350030; called by muse, varscan2
